Gene-level copy-number profile of tumor specimen TCGA-06-0133-01A from TCGA case TCGA-06-0133, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.1 years (23,402 days).
Specimen TCGA-06-0133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.cd1b1b1b-3e10-4672-81ad-096c205da56a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0133-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a091c005-d1c5-4296-9a81-5e494aae192c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 5,096; copy number 2: 42,132; copy number 3: 9,694; copy number 4: 2,189; copy number 5: 619; copy number 6: 40; copy number 39: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0133-01): tumor purity 0.56, ploidy 2.21, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 694 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:28,299,321–28,959,345, 4 genes, copy number 5 (within-gene range 4–5): CREB5, AC005105.1, TRIL, AC005013.1.
- chr7:39,329,003–42,264,100, 35 genes, copy number 6: SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1, LINC01450, LINC01449, INHBA, INHBA-AS1, GLI3, HMGN2P30.
- chr7:48,846,426–49,254,816, 5 genes, copy number 6 (within-gene range 4–6): AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1.
- chr7:52,891,837–87,059,654, 650 genes, copy number 5–39 (within-gene range 4–39) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
